Surgical pathology report (de-identified scan), TCGA case TCGA-2Y-A9GS, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Moffitt Cancer Center, specimen TCGA-2Y-A9GS-01A (Primary Tumor).

[page 1 of 2]
Pathology Report

Gender: M Service: Received:
Reported:
Submitting Physician:
Pathologist:
Intraop Pathologist:
Performing Physician:

CLINICAL HISTORY:
LIVER MASS.

PREOPERATIVE DIAGNOSIS:
NOT GIVEN.

SPECIMEN TYPE(S):
A: SEGMENT 6 LIVER LESION
B: GALLBLADDER
C: ADDITIONAL GALLBLADDER MARGIN

FINAL DIAGNOSIS:
A. LIVER, SEGMENT 6 LESION, EXCISION:
Hepatocellular carcinoma, clear cell type (see Key Pathological Findings).
B. GALLBLADDER, CHOLECYSTECTOMY:
Chronic cholecystitis.
There is no evidence of malignancy.
C. LIVER (SUBMITTED AS GALLBLADDER, ADDITIONAL MARGIN) EXCISION:
Hepatic parenchyma with chronic hepatitis, negative for malignancy.

KEY PATHOLOGICAL FINDINGS

Tumor type: Hepatocellular carcinoma, clear cell type
Tumor configuration: Nodular
Tumor size: 6.0 x 5.0 x 4.5 cm *pw TSS, clear cell = 5%*
Histologic grade: Moderately differentiated
Tumor necrosis: Approximately 25%
Perineural invasion: Not identified
Angiolymphatic invasion: Present
Surgical margin: Additional surgical margin free of tumor
Additional pathologic findings: Chronic hepatitis with moderate interface hepatitis and
mild to moderate lobular hepatitis
Bridging fibrosis, consistent with cirrhosis
Mild macrovesicular steatohepatitis.
Lymph nodes: None identified
Pathologic stage: T2 NX MX.

I, the attending pathologist, personally reviewed the entire
pathology case and rendered the final diagnosis. Electronically Signed out by

OTHER RELATED CLINICAL DATA:
NA

INTRAOPERATIVE DIAGNOSIS:
FROZEN SECTION DIAGNOSIS

ICD-O-3
Carcinoma, hepatocellular NOS
8170/3
Site: Liver C22.0
J 4/28/14

[page 2 of 2]
- A. SEGMENT 6 LIVER LESION:
Surgical margin grossly involved.
Inked surgical margin involved by carcinoma.

COMMENT: This frozen section diagnosis/result was communicated to and acknowledged by
in. at.

have performed the intraoperative
consultation and issued the above diagnoses.

GROSS DESCRIPTION:

- A. Specimen A is received fresh for OR consult, labeled "segment 6 liver lesion, frozen section". The specimen consists of a 153.5 gram, 15.0 x 9.0 x 5.0 cm lobe of liver. The capsule is intact. The entire surgical margin is marked with black ink. A palpable mass is grossly appreciated. Serial sections reveal a moderately firm, gray-tan nodular ill-defined mass, which measures 6.0 x 5.0 x 4.5 cm in overall dimension. Grossly, the mass approximates the surgical margin of resection. Some hemorrhage and necrosis (approximately 25%) is identified on the cut surface of the mass. The remaining hepatic parenchyma is grossly unremarkable. A representative frozen section is taken and submitted as PSA1. Permanent sections are submitted as:
A1-A3: Tumor showing its relationship to adjacent tissue.
A4: Grossly unremarkable hepatic parenchyma.
- B. Specimen B is labeled "gallbladder". The specimen is received fresh and consists of a disrupted, glove-shaped, gallbladder, which measures 7.5 x 3.0 x 2.0 cm. The outer surface is gray/red-brown, congested. There is a stapled margin, which is removed, and the underlying tissue is marked with black ink. Upon completion of opening, no calculus is grossly identified. The mucosal surface is gray-yellow and finely reticulated. There is some marked thickening of the wall. Representative sections are submitted as:
B1: Tangential surgical margin.
B2-B3: Representative sections from gallbladder.
- C. Specimen C is labeled "additional gallbladder margin". The specimen is received fresh, and consists of a 4.5 x 3.0 x 3.0 cm, red-brown irregular fragment of liver with a stapled margin. This is removed and the underlying tissue is marked with black ink. This margin is removed and entirely submitted. The remaining tissue is serially sectioned and is grossly unremarkable. Representative sections are submitted as:
C1-C2: Entire surgical margin.
C3: Grossly unremarkable hepatic parenchyma.

Dual/Synchronous Primary	Noted	

Source: NCI Genomic Data Commons file c6deaf59-f476-4994-bdae-8893ed474e81 (TCGA-2Y-A9GS.DAA3D158-0488-41C9-8B3F-BE6D05E036D8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).